Somatic mutation profile of tumor specimen TARGET-10-PANWDN-09A (aliquot TARGET-10-PANWDN-09A-01D) from TARGET case TARGET-10-PANWDN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,479 days).
Specimen TARGET-10-PANWDN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1408032e-6a68-4e3e-b14a-2d38563d16e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWDN-14A (Bone Marrow Normal), aliquot TARGET-10-PANWDN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ede5cdb-de3a-4699-8758-fb76a502dff0

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 5'UTR 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 51/84 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POLR3A | c.1800C>T p.I600= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs1564620047; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABT1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782670086; called by muse, mutect2, varscan2
- CRTAC1 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291719945; called by muse, mutect2, varscan2
- OAS3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs548511751; called by muse, mutect2, varscan2
- ZNF467 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV57372741; called by muse, mutect2, varscan2
- C19orf57 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 52/127 reads (41%) | called by muse, mutect2, varscan2
- FAM117B | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FAM160B2 | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CC2D2A | c.2934A>G p.S978= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- NSD3 | c.1959C>T p.S653= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs764548951, COSV57621824; called by muse, mutect2, varscan2
- FKBP15 | c.*4264T>C | 3'UTR (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- PTBP2 | c.-28T>G | 5'UTR (SNP) | VAF 9/56 reads (16%) | catalogued as COSV64625429; called by muse, mutect2, varscan2
